CCDI case PBBNWV — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/782803f4-e1bb-457a-9d17-823dad4ad509

Demographics
Sex at birth: male; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Ependymoma, NOS: ICD-O-3 morphology code: 9391/3; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 4.4 years (1,616 days).

Biospecimens (3 samples)
- Sample 0DDHVL: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DDHVM: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DDHVN: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
